Somatic mutation profile of tumor specimen TCGA-AB-2877-03A (aliquot TCGA-AB-2877-03A-01W-0732-08) from TCGA case TCGA-AB-2877, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.1 years (21,946 days).
Specimen TCGA-AB-2877-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88019cd5-e926-4626-a44c-4e15b07db746.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2877-11A (Solid Tissue Normal), aliquot TCGA-AB-2877-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c77a4a1-8ada-4108-abc6-7842d2218d05

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 63/142 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 15/61 reads (25%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, varscan2
- ADGRG4 | c.5681C>T p.P1894L | Missense Mutation (SNP) | VAF 380/1004 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV54954235; called by muse, mutect2, varscan2
- EEA1 | c.3812C>T p.T1271M | Missense Mutation (SNP) | VAF 471/1106 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs187203462, COSV59285015; called by muse, mutect2, varscan2
- ELMOD1 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56191372; called by muse, mutect2, varscan2
- FLRT1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs774763930, COSV55359339; called by muse, mutect2, varscan2
- IGSF9B | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1333086571, COSV58065145, COSV58074919; called by muse, mutect2, varscan2
- KLF15 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs775981060, COSV56179851; called by muse, mutect2, varscan2
- PKNOX1 | c.1051G>C p.A351P | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV52335511; called by muse, mutect2, varscan2
- PLPPR1 | c.974C>T p.T325I | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1355089096, COSV66452472; called by muse, varscan2
- STRIP2 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as rs762567887, COSV50803968; called by muse, mutect2, varscan2
- UNC45B | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV52094605; called by muse, varscan2
- XKR4 | c.1195C>A p.L399M | Missense Mutation (SNP) | VAF 302/864 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59311363; called by muse, varscan2
- CSPG4 | c.1998C>T p.H666= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs758415316, COSV57893906; called by muse, mutect2, varscan2
- FLRT2 | c.255C>T p.H85= | Silent (SNP) | VAF 163/358 reads (46%) | catalogued as rs746240615, COSV58140036; called by muse, mutect2, varscan2
